Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A67L, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A67L-01A (Primary Tumor).

[page 1 of 4]
MRN
Name
Encounter Number

Gender M
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Final

Results

Final

Source of Specimen

- A. LEFT PELVIC LYMPH NODES-
- B. TISSUE OVER PROSTATE-
- C. PROSTATE GLAND, SEMINAL VESICLES AND VAS DEFERENS-

FINAL DIAGNOSIS:

- A. LEFT PELVIC LYMPH NODES-
ONE LYMPH NODE, NO TUMOR SEEN.
- B. TISSUE OVER PROSTATE-
ONE LYMPH NODE, NO TUMOR SEEN.
- C. PROSTATE GLAND, SEMINAL VESICLES AND VAS DEFERENS-
ADENOCARCINOMA OF PROSTATE WITH UNILATERAL EXTENSION INTO
EXTRAPROSTATIC SOFT TISSUE.

TUMOR SITE: LEFT SIDE.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 42 GRAMS.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 4 = 7/10.

TNM STAGE: pT3a, pN0, pMX.

PERINEURAL INVASION: IS PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT MARGINS OF PROSTATE, SOFT TISSUE, URETHRA AND

Prepared for

path ICD-O-3
Adenocarcinoma NOS 8140/3
Adenocarcinoma, acinar 8140/3
Site: Prostate NOS C61.9
7/5/13

Criteria	Path 4/12/13	MA	✓
Diagnosis Discrepancy	1-3, white	MA	✓

[page 2 of 4]
BLADDER NECK.

Signature

(Case signed

Case Clinical Information
PROSTATE CANCER

Gross Description

A. Received in formalin labeled with the patient's name and "left pelvic lymph node" is a yellow-tan fibroadipose tissue measuring 2 x 1.5 x 1.0 cm. One lymph node was identified measuring 0.7 x 0.3 cm bisected and entirely submitted in A1.

B. Received in formalin labeled with the patient's name and "tissue over prostate" is a yellow-tan adipose tissue fragment measuring 32.5 x 2.5 x 1.5 cm. The specimen is serially sectioned showing a yellow and tan adipose cut surface and entirely submitted in B1-B4.

C. Received in formalin labeled with the patient's name and "prostate gland, seminal vesicles and vas deferens" is a radical prostatectomy specimen which includes a 42 gram prostate gland with attached seminal vesicle and vas deferens. The prostate gland measures 5 x 4.5 x 4.0 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 2 x 1.2 cm. The right vas measures 2.0 x 0.4 cm. The left seminal vesicle measures 2 x 1.5 cm. The left vas measures 3 x 0.4 cm. The inferior prostate is sectioned transversely, removed from the rest of the specimen and sectioned from anterior to posterior parallel to the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no abnormalities. Representative sections submitted as follows: inferior prostate demonstrating apical margin submitted entirely anterior to posterior in C1-C6 ; bladder resection margin; is a perpendicular resection and entirely submitted in C7-C8; complete section of mid gland anterior C9-C10; posterior C11-C12; complete section of upper third of gland, anterior C13-C14; posterior C15-C16; remainder of the posterior gland entirely submitted in C17-C20; right seminal vesicle and vas deferens C21; left seminal vesicle and vas deferens C22. Also in the same container there are two cassettes the first one is labeled "tumor" which is submitted in C23; the second cassette is labeled "normal" which is submitted in C24. 85% of the specimen is represented.

Prepared for _____ on _____

[page 3 of 4]
Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK
H&E X1
B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
B. AA ROUTINE H&E X1 BLOCK.2
H&E X1
B. AA ROUTINE H&E X1 BLOCK.3
H&E X1
B. AA ROUTINE H&E X1 BLOCK.4
H&E X1
C. AA ROUTINE H&E X1 BLOCK.1
H&E X1
C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
C. AA ROUTINE H&E X1 BLOCK.3
H&E X1
C. AA ROUTINE H&E X1 BLOCK.4
H&E X1
C. AA ROUTINE H&E X1 BLOCK.5
H&E X1
C. AA ROUTINE H&E X1 BLOCK.6
H&E X1
C. AA ROUTINE H&E X1 BLOCK.7
H&E X1
C. AA ROUTINE H&E X1 BLOCK.8
H&E X1
C. AA ROUTINE H&E X1 BLOCK.9
H&E X1
C. AA ROUTINE H&E X1 BLOCK.10
H&E X1
C. AA ROUTINE H&E X1 BLOCK.11
H&E X1
C. AA ROUTINE H&E X1 BLOCK.12
H&E X1
C. AA ROUTINE H&E X1 BLOCK.13
H&E X1
C. AA ROUTINE H&E X1 BLOCK.14
H&E X1
C. AA ROUTINE H&E X1 BLOCK.15
H&E X1
C. AA ROUTINE H&E X1 BLOCK.16
H&E X1

Prepared for:

[page 4 of 4]
C. AA ROUTINE H&E X1 BLOCK.17
H&E X1
C. AA ROUTINE H&E X1 BLOCK.18
H&E X1
C. AA ROUTINE H&E X1 BLOCK.19
H&E X1
C. AA ROUTINE H&E X1 BLOCK.20
H&E X1
C. AA ROUTINE H&E X1 BLOCK.21
H&E X1
C. AA ROUTINE H&E X1 BLOCK.22
H&E X1
C. AA ROUTINE H&E X1 BLOCK.23
H&E X1
C. AA ROUTINE H&E X1 BLOCK.24
H&E X1

Prepared for

Source: NCI Genomic Data Commons file fe9d475d-cb6d-4718-9f4b-b90aaca10f19 (TCGA-J4-A67L.91F854F5-D488-4B25-B59A-6CB59C6357BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).